Somatic mutation profile of tumor specimen TCGA-85-6175-01A (aliquot TCGA-85-6175-01A-11D-1817-08) from TCGA case TCGA-85-6175, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.6 years (23,228 days).
Specimen TCGA-85-6175-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed7213da-5cde-4768-9f86-2ee0a1cc8008.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-6175-10A (Blood Derived Normal), aliquot TCGA-85-6175-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a0faea6-311a-43df-aee4-7658faf82401

The open-access MAF lists 39 somatic variants for this specimen: 25 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 12, Nonsense Mutation 4, In Frame Del 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.6855C>A p.Y2285* (on ENST00000358273 / NM_001042492.3; = p.Y2264* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 21/153 reads (14%) | catalogued as rs772295894, CM972796, CM981382, COSV62214006, COSV62218349; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP6V1H | c.1065C>G p.Y355* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV62220100; called by muse, mutect2, varscan2
- BNC2 | c.3209G>T p.C1070F | Missense Mutation (SNP) | VAF 106/153 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66175078; called by muse, mutect2, varscan2
- CASKIN2 | c.3168C>A p.S1056R | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as COSV58599380; called by muse, mutect2, varscan2
- COL6A3 | c.5734G>A p.E1912K | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs113251155, COSV55115128; ClinVar: uncertain significance; called by muse, mutect2
- CYP11B2 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.06); catalogued as COSV59997626; called by muse, mutect2, varscan2
- F8 | c.1463C>A p.A488E | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM010850, CM950399, HM070049, COSV64277989; called by muse, mutect2, varscan2
- GNAZ | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs766030793, COSV50737047; called by muse, mutect2, varscan2
- GNB1L | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs372693569, COSV61549715; called by muse, mutect2, varscan2
- GRIK3 | c.2170G>T p.E724* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV66145943; called by muse, mutect2, varscan2
- HIVEP3 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 6/79 reads (8%) | catalogued as COSV56009059; called by muse, mutect2
- HSPA5 | c.935T>C p.F312S | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52338006; called by muse, mutect2, varscan2
- MCF2 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV58494001; called by muse, mutect2
- MYH7 | c.3321G>C p.K1107N | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62523151; called by muse, mutect2, varscan2
- NRIP2 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV61702051; called by muse, mutect2, varscan2
- OBP2A | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1206641570, COSV59792794; called by muse, mutect2, varscan2
- PAK1 | c.1371G>A p.M457I | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53700820; called by muse, mutect2
- TIAM2 | c.4818G>T p.Q1606H (on ENST00000529824; = p.Q1577H on NM_012454.3) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV51644209; called by muse, mutect2, varscan2
- TRIM51 | c.500G>T p.C167F | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV55270376; called by muse, mutect2
- TSSK6 | c.520T>G p.S174A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53065046; called by mutect2, varscan2
- TUBA3E | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs371431005; called by muse, mutect2, varscan2
- UBR7 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs535218313, COSV50151080; called by muse, mutect2, varscan2
- USP54 | c.3623T>C p.L1208P | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV60447158; called by muse, mutect2, varscan2
- ZBTB11 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100465617, COSV57246766; called by muse, mutect2, varscan2
- GUSB | c.833_844del p.G278_K281del | In Frame Del (DEL) | VAF 11/92 reads (12%) | called by mutect2, pindel, varscan2
- ACTR5 | c.1581G>A p.S527= | Silent (SNP) | VAF 33/147 reads (22%) | catalogued as rs202083819; called by muse, mutect2, varscan2
- BOK | c.525C>T p.L175= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV59192264, COSV59193016; called by muse, mutect2, varscan2
- C8A | c.1119G>A p.T373= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as rs147666641; called by muse, mutect2, varscan2
- CYP4A22 | c.1452C>T p.P484= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV53742229; called by muse, mutect2, varscan2
- HAS2 | c.516G>A p.T172= | Silent (SNP) | VAF 39/398 reads (10%) | catalogued as rs777875515, COSV100391485, COSV58262635; called by muse, varscan2
- KIAA0100 | c.1920A>G p.P640= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV66495934; called by muse, mutect2
- PRAMEF14 | c.1419C>T p.C473= | Silent (SNP) | VAF 23/103 reads (22%) | called by mutect2, varscan2
- SLC8A1 | c.876C>T p.D292= | Silent (SNP) | VAF 41/280 reads (15%) | catalogued as rs201010344; called by muse, mutect2, varscan2
- SLITRK1 | c.168G>A p.P56= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as rs1475625099, COSV65677303; called by muse, mutect2, varscan2
- SYK | c.1308C>T p.I436= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as rs201416422, COSV65329979; called by muse, mutect2, varscan2
- TOP3A | c.381A>T p.V127= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs1244961169, COSV58180677; called by muse, mutect2, varscan2
- ZNF473 | c.2217C>T p.F739= | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as rs779467075, COSV54524126; called by muse, mutect2, varscan2
- CBARP | c.1214+20G>A | Intron (SNP) | VAF 10/36 reads (28%) | catalogued as rs760087675, COSV53071395; called by muse, mutect2, varscan2
- VKORC1 | chr16:31095483 C>G | 5'Flank (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100161597; called by muse, mutect2, varscan2
